TCGA case TCGA-BC-A10T — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8a9cde9a-c38c-423e-bc14-354ee26468c9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Dead; Days to death: 837 days (2.3 years).

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 76.5 years (27,944 days); Year of diagnosis: 2000; AJCC staging edition: 5th; AJCC pathologic T: T4; AJCC pathologic N: NX; AJCC pathologic M: MX; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Ishak fibrosis score: 1,2 - Portal Fibrosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 78.1 years (28,542 days); Days to diagnosis: 598 days (1.6 years); Prior treatment: Yes.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 598 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 598 days (1.6 years).
- Days to follow up: 837 days (2.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- Albumin 3 (unit not recorded on the TCGA source form).
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.1.
- Total Bilirubin 0.7 mg/dL.
- Creatinine 1.2 mg/dL.
- Platelets 450000 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 440].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 86 kg.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BC-A10T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 1,000 mg.
  Slide TCGA-BC-A10T-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BC-A10T-01A-01-BSA: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BC-A10T-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BC-A10T-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 480 mg.
  Slide TCGA-BC-A10T-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Surgical procedure other: R hepatic lobectomy w/ resection of L segment.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 837 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 837 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 598 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BC-A10T-01A-11D-A12Y-01): tumor purity 0.7, ploidy 2.03, whole-genome doublings 0.
